CCDI case PBCNVJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Peripheral nerves and autonomic nervous system.
https://portal.gdc.cancer.gov/cases/aca1afe2-16a0-455b-952d-b88f8118a301

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Malignant peripheral nerve sheath tumor: ICD-O-3 morphology code: 9540/3; Tissue or organ of origin: Autonomic nervous system, NOS; Age at diagnosis: 9.5 years (3,471 days).

Biospecimens (3 samples)
- Sample 0DWKG8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWKGU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWKHA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
